Somatic mutation profile of tumor specimen TCGA-ZN-A9VS-01A (aliquot TCGA-ZN-A9VS-01A-11D-A39R-32) from TCGA case TCGA-ZN-A9VS, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 67.0 years (24,490 days).
Specimen TCGA-ZN-A9VS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 421c903c-7793-49dc-b822-98b39d9d3345.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZN-A9VS-10A (Blood Derived Normal), aliquot TCGA-ZN-A9VS-10A-01D-A39U-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c43ffd8f-2562-4a58-b948-293f8efb2d46

The open-access MAF lists 42 somatic variants for this specimen: 30 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, 3'UTR 1, Frame Shift Ins 1, Intron 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BNIP5 | c.1675C>T p.R559C | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs768042350; called by muse, mutect2, varscan2
- C1orf94 | c.1685G>A p.G562E (on ENST00000488417 / NM_001134734.2; = p.G372E on NM_032884.5) | Missense Mutation (SNP) | VAF 67/266 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100975063; called by muse, mutect2, varscan2
- COQ4 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 196/556 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs1223476791, COSV55956387; called by muse, mutect2, varscan2
- FANCA | c.49G>T p.G17C | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); catalogued as rs982957228; called by muse, mutect2, varscan2
- NRXN3 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.049); catalogued as rs201052888; called by muse, mutect2, varscan2
- OR2C3 | c.367C>A p.R123S | Missense Mutation (SNP) | VAF 160/542 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV63574391, COSV63575140; called by muse, mutect2, varscan2
- PCDHA1 | c.351C>G p.F117L | Missense Mutation (SNP) | VAF 89/276 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV65373297; called by muse, mutect2, varscan2
- PCDHA2 | c.1499G>A p.G500D | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.34); catalogued as COSV100973430; called by muse, mutect2, varscan2
- PCDHB5 | c.761A>G p.N254S | Missense Mutation (SNP) | VAF 89/269 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.192); catalogued as rs1434275598; called by muse, mutect2, varscan2
- PLIN2 | c.943C>G p.R315G | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs183420763; called by muse, mutect2, varscan2
- TBX2 | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99538901; called by muse, mutect2, varscan2
- TPP1 | c.610G>A p.V204M | Missense Mutation (SNP) | VAF 168/558 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV54993573; called by muse, mutect2, varscan2
- TSC1 | c.3478C>T p.H1160Y | Missense Mutation (SNP) | VAF 113/374 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as rs1470270925; called by muse, mutect2, varscan2
- TTN | c.14514G>T p.K4838N (on ENST00000591111; = p.K3911N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | PolyPhen possibly damaging (0.787); catalogued as rs1215311775; called by muse, mutect2, varscan2
- USP8 | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1443618535; called by muse, mutect2, varscan2
- ZNF169 | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs762656741, COSV61764168; called by muse, mutect2, varscan2
- A2ML1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.065); called by muse, mutect2
- CPM | c.593A>G p.Y198C | Missense Mutation (SNP) | VAF 60/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FTSJ3 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1553T>C p.M518T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LVRN | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 113/334 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MSL2 | c.1171G>A p.G391R | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PYGB | c.1747C>A p.H583N | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- RPS6 | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SETD5 | c.88dup p.A30Gfs*2 | Frame Shift Ins (INS) | VAF 15/115 reads (13%) | called by mutect2, pindel, varscan2
- SLC7A3 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 96/178 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- SLIT1 | c.4598G>T p.C1533F | Missense Mutation (SNP) | VAF 46/295 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TRH | c.527G>T p.R176I | Missense Mutation (SNP) | VAF 75/431 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.404); called by muse, mutect2, varscan2
- USP9X | c.1936del p.S646Vfs*20 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | called by mutect2, pindel, varscan2
- WDR55 | c.14G>A p.C5Y | Missense Mutation (SNP) | VAF 137/461 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ABCG1 | c.642C>A p.T214= | Silent (SNP) | VAF 74/253 reads (29%) | catalogued as COSV59204099; called by muse, mutect2, varscan2
- CPNE6 | c.1434C>T p.D478= | Silent (SNP) | VAF 100/489 reads (20%) | called by muse, mutect2, varscan2
- DUSP16 | c.1461C>T p.V487= | Silent (SNP) | VAF 155/539 reads (29%) | called by muse, mutect2, varscan2
- NAP1L3 | c.1161T>C p.D387= | Silent (SNP) | VAF 25/42 reads (60%) | called by muse, mutect2, varscan2
- NPHS1 | c.3084G>A p.G1028= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as rs767506475, COSV100800224; ClinVar: likely benign; called by muse, mutect2, varscan2
- PROKR2 | c.747G>A p.E249= | Silent (SNP) | VAF 236/751 reads (31%) | called by muse, mutect2, varscan2
- SLC5A7 | c.1674C>T p.T558= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV99886549; called by muse, mutect2, varscan2
- TYR | c.300T>C p.C100= | Silent (SNP) | VAF 43/144 reads (30%) | catalogued as CM100986; called by muse, mutect2, varscan2
- ZPLD1 | c.939C>T p.C313= (on ENST00000466937 / NM_001329788.1; = p.C329= on NM_175056.2) | Silent (SNP) | VAF 62/232 reads (27%) | called by muse, mutect2, varscan2
- DPP6 | c.627+20813G>A | Intron (SNP) | VAF 42/192 reads (22%) | called by muse, mutect2, varscan2
- LRRC27 | chr10:132331562 G>A | 5'Flank (SNP) | VAF 124/385 reads (32%) | called by muse, mutect2, varscan2
- SZT2 | c.*400G>A | 3'UTR (SNP) | VAF 123/378 reads (33%) | catalogued as rs930828130; called by muse, mutect2, varscan2
